Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A878, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A878-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD0-3

Adenocarcinoma, acinar
8140/3

Site Prostate NOS
C61.9

11/21/13

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: Urology

Accession #: [REDACTED]

Location: [REDACTED]

Gender: M

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Physician(s): [REDACTED]

Other Related Clinical Data:

DIAGNOSIS:

PROSTATE, RADICAL PROSTATECTOMY

- ADENOCARCINOMA, GLEASON GRADE 4 + 5 = SCORE 9 INVOLVING ALL FOUR QUADRANTS AND APPROXIMATELY 40% OF SAMPLED TISSUE (SEE SYNOPTIC)

- LYMPHATIC AND PERINEURAL INVASION IDENTIFIED

- TUMOR PRESENT AT RESECTION MARGIN

- NO EXTRAPROSTATIC EXTENSION IDENTIFIED

- RARE NON-NECROTIZING GRANULOMA

LYMPH NODES, BILATERAL PELVIC, DISSECTION

- METASTATIC ADENOCARCINOMA IN ONE OF THREE LYMPH NODES (1/3)

SEMINAL VESICLES, BILATERAL, RADICAL PROSTATECTOMY

- NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'prostate' consisting of a 55 gram, 5 x 4.5 x 4.5 cm prostate with attached bilateral seminal vesicles measuring 3 x 1.2 x 0.6 cm, on the right, and 3.4 x 1.5 x 0.6 cm on the left. The right vas deferens measures 2 x 0.4 x 0.4 cm and the left vas deferens measures 3 x 0.4 x 0.4 cm. Inked. Tissue taken from left and right lobes for research. Rest for permanents," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

[page 2 of 5]
Patient Name: [REDACTED]

History:

The patient is a [REDACTED] year old man who has prostate carcinoma. Operative procedure: Laparoscopic radical prostatectomy.

Specimen(s) Received:

A: PROSTATE

B: LYMPH NODE, BILATERAL PELVIC

Gross Description

The specimens are received in two formalin-filled containers, each labeled [REDACTED]. The first container is labeled "prostate." It contains a 65-gram, 5 x 4.5 x 4.0 cm prostate with attached bilateral seminal vesicles measuring 3 x 1.2 x 0.6 cm, on the right, and 3.4 x 1.5 x 0.6 cm on the left. The specimen has been previously inked black and there are defects in both lobes where tissue has been previously taken for research, measuring 2.5 cm, on the right, and 2.0 cm on the left. The prostate is sectioned to show a tan, unremarkable cut surface. The urethral mucosa is tan and smooth. The seminal vesicles are sectioned to show unremarkable cut surfaces. Labeled A1 and A2 - right prostate apex; A3 and A4 - right base; A5 and A6 - left apex; A7 and A8 - left base; A9 - right seminal vesicle; A10 - left seminal vesicle; A11 - right apical margin; A12 - left apical margin; A13 - right bladder base margin; A14 - left bladder base margin. Jar 2.

The second container is labeled "bilateral pelvic lymph nodes." It contains numerous fragments of yellow-tan fibroadipose tissue measuring, in aggregate, 8.5 x 6.0 x 1.7 cm. Multiple, unremarkable lymph nodes are dissected measuring up to 3.7 cm. Labeled B1 to B2 - multiple lymph nodes; B3 - single section of largest lymph node; B4 - half of bisected lymph node; B5 - half of bisected lymph node. Jar 1.

A. PROSTATE:

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 40%

GLEASON'S GRADE

The Gleason's Grade is 4 + 5

TUMOR LOCATION

The location of the tumor involves the
right base
right apex
left base
left apex

PERINEURAL INVASION

Perineural Invasion is identified

VASCULAR INVASION

[page 3 of 5]
Patient Name: [REDACTED]

Vascular Invasion is not identified
Lymphatic invasion is identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is absent

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

Tumor is present at sampled peripheral margin of resection in the (specify site) right apex, right apical margin, left apical margin, without extra prostatic extension

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)
bilateral pelvic lymph nodes: 1/3

Extranodal extension by tumor metastases is absent

PRIMARY TUMOR (T)

Tumor involves both lobes (T2c)

REGIONAL LYMPH NODES (N)

Metastasis in regional lymph node(s) (N1)

DISTANT METASTASIS

No distant metastasis reportedly present (M0)

STAGE GROUPING

T2/N1/M0 (Stage IV)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in this report (if any) were determined by the

part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the

Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

[page 4 of 5]
Patient Name: [REDACTED]

This test was developed and its performance characteristics determined by the [REDACTED] It has not been cleared or approved by the U. S. Food and Drug Administration.

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is 4+5=9	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is 4+4=8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Review

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file edbb82d0-634c-4adc-9231-841a73ce21ea (TCGA-VP-A878.635464F3-6A6B-4574-8413-058651AB4068.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).